Somatic mutation profile of tumor specimen TCGA-BJ-A3PR-01A (aliquot TCGA-BJ-A3PR-01A-11D-A21Z-08) from TCGA case TCGA-BJ-A3PR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 70.0 years (25,565 days).
Specimen TCGA-BJ-A3PR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afe40796-a026-4fa2-b402-b80d0f29760c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A3PR-10A (Blood Derived Normal), aliquot TCGA-BJ-A3PR-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/608d0c64-ac27-4f8f-bc19-5709017d43f5

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP192 | c.6721T>G p.L2241V | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.271); catalogued as COSV58065015; called by muse, mutect2
- CSMD2 | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 26/435 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs750515208, COSV53888438; called by muse, mutect2
- HLA-DRA | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs530789959, COSV66622719; called by muse, mutect2
- OR4X1 | c.139A>T p.I47F | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV60723029; called by muse, mutect2, varscan2
- SPTBN4 | c.3647G>A p.R1216H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1455686863, COSV58950624; called by muse, mutect2
- ENPEP | c.432C>T p.L144= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as COSV54446970; called by muse, mutect2
- VPS13C | c.771C>T p.A257= (on ENST00000644861 / NM_020821.3; = p.A214= on NM_017684.5) | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as COSV51198823; called by muse, mutect2
